Gene-level copy-number profile of tumor specimen ALCH-AE09-TTP1-A from ALCHEMIST case ALCH-AE09, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.5 years (23,198 days).
Specimen ALCH-AE09-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cea96f09-63f9-404f-bf61-898b50794963.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE09-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/1ff9f856-f361-4591-a129-2eed81c5ef0c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 2,922; copy number 2: 44,430; copy number 3: 10,976; copy number 4: 18; copy number 5: 7; copy number 6: 1; copy number 7: 4; copy number 8: 35; copy number 11: 1; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,281,444–60,546,660, 1 gene: AC244258.1.
- chr15:21,307,749–21,307,855, 1 gene (within-gene range 0–2): RNU6-1235P.
- chr22:18,833,694–18,834,438, 1 gene (within-gene range 0–2): E2F6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,621,116–105,621,180, 1 gene, copy number 6: MIR8071-1.
- chr15:21,328,380–21,981,245, 37 genes, copy number 5–11: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P.
- chr15:22,125,511–22,202,734, 8 genes, copy number 5–7 (within-gene range 4–7): OR4N3P, AC010760.1, RPS8P10, IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8, IGHV1OR15-4, AC025884.3.
- chr22:18,936,411–18,947,741, 1 gene, copy number 16 (within-gene range 2–16): AC007326.5.
- chr22:21,125,660–21,142,371, 2 genes, copy number 5: POM121L7P, E2F6P2.

Autosomal genes at a single copy (total copy number 1): 2,922. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
